Somatic mutation profile of tumor specimen 0DPHAN from CCDI case PBCDKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.8 years (6,852 days).
Specimen 0DPHAN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64796538-adfd-42b6-ae96-c5ee52760b76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPH9Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c6394f4-6257-4ddd-880c-cca8a78bfeeb

The open-access MAF lists 43 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 11, Intron 6, 5'UTR 3, Splice Site 3, 3'UTR 2, Nonsense Mutation 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBRA1 | c.2632+1G>A p.X878_splice (on ENST00000458649 / NM_001367468.1; = p.X788_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 127/279 reads (46%) | catalogued as COSV100094179; called by muse, mutect2, varscan2
- BX276092.9 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs969679021, COSV70724288; called by muse, mutect2
- C7orf31 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 468/1094 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs150213134, COSV52217612; called by muse, mutect2, varscan2
- CACNA1H | c.5498C>T p.P1833L | Missense Mutation (SNP) | VAF 92/556 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs555953199; called by muse, mutect2, varscan2
- NID1 | c.3130C>T p.R1044* | Nonsense Mutation (SNP) | VAF 244/938 reads (26%) | catalogued as COSV99938317; called by muse, mutect2, varscan2
- PRKDC | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 75/870 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs977593814; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 54/1449 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CACNA2D1 | c.3046A>G p.I1016V (on ENST00000356253 / NM_001366867.1; = p.I1004V on NM_000722.4) | Missense Mutation (SNP) | VAF 347/957 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- FAM118A | c.1055-1G>A p.X352_splice | Splice Site (SNP) | VAF 205/871 reads (24%) | called by muse, mutect2, varscan2
- FAM47C | c.2438G>T p.C813F | Missense Mutation (SNP) | VAF 79/429 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPAT3 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 68/506 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, varscan2
- KAT2A | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- LIMS2 | c.171+2T>C p.X57_splice (on ENST00000355119 / NM_001161403.3; = p.X81_splice on NM_017980.4) | Splice Site (SNP) | VAF 123/442 reads (28%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1748+6T>G | Splice Region (SNP) | VAF 65/498 reads (13%) | called by muse, mutect2, varscan2
- RETREG3 | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 33/1190 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHANK1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 72/419 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TCAF1 | c.2728A>G p.I910V | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- UNC5D | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 117/546 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTF1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2
- WWP2 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF284 | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 138/807 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AAK1 | c.373C>T p.L125= | Silent (SNP) | VAF 82/914 reads (9%) | catalogued as rs528620333; called by muse, mutect2
- CMSS1 | c.624G>T p.L208= | Silent (SNP) | VAF 93/869 reads (11%) | called by muse, mutect2, varscan2
- EPHB6 | c.1110T>C p.P370= | Silent (SNP) | VAF 108/706 reads (15%) | catalogued as rs1460038746; called by muse, mutect2, varscan2
- FAT4 | c.9006G>A p.T3002= | Silent (SNP) | VAF 122/1890 reads (6%) | catalogued as rs142357260; called by muse, mutect2
- LTBP1 | c.3066C>T p.C1022= (on ENST00000404816 / NM_206943.4; = p.C696= on NM_000627.4) | Silent (SNP) | VAF 108/749 reads (14%) | catalogued as rs763312851, COSV100618042; called by muse, mutect2, varscan2
- MAP1A | c.6363G>A p.E2121= | Silent (SNP) | VAF 69/658 reads (10%) | catalogued as rs374833932; called by muse, mutect2, varscan2
- RETREG3 | c.483C>T p.F161= | Silent (SNP) | VAF 33/1197 reads (3%) | called by muse, mutect2
- SLC38A10 | c.3096G>A p.P1032= | Silent (SNP) | VAF 30/356 reads (8%) | catalogued as rs371749316; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 44/1387 reads (3%) | called by muse, mutect2
- UNC13B | c.2928G>C p.V976= | Silent (SNP) | VAF 90/999 reads (9%) | catalogued as COSV65934988; called by muse, mutect2
- WDR64 | c.2481G>A p.T827= | Silent (SNP) | VAF 278/1191 reads (23%) | catalogued as rs1017174137, COSV100843689; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*19+66C>G | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs920395245, COSV101374590; called by muse, varscan2
- LRRC3 | c.-66G>A | 5'UTR (SNP) | VAF 19/35 reads (54%) | catalogued as rs1008172828, COSV52399726, COSV99381690; called by muse, mutect2, varscan2
- NDUFB1 | c.*12A>C | 3'UTR (SNP) | VAF 72/710 reads (10%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV55814242; called by muse, mutect2
- PTCD2 | c.*37G>A | 3'UTR (SNP) | VAF 44/216 reads (20%) | catalogued as rs184594147; called by muse, varscan2
- SAP25 | c.-127-28C>A | Intron (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- SDE2 | c.-20A>G | 5'UTR (SNP) | VAF 15/134 reads (11%) | catalogued as rs1424908462; called by muse, mutect2, varscan2
- SLC25A37 | c.-19C>A | 5'UTR (SNP) | VAF 44/224 reads (20%) | catalogued as rs764351095; called by muse, mutect2
- SUGCT | c.1090-65324C>T | Intron (SNP) | VAF 101/558 reads (18%) | called by muse, mutect2, varscan2
- TMEM230 | c.-16+61G>A | Intron (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- TSPEAR | c.1150-42G>A | Intron (SNP) | VAF 25/110 reads (23%) | catalogued as rs374192283; called by muse, mutect2, varscan2
